Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8NB, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8NB-01A (Primary Tumor).

[page 1 of 3]
File Copy

DOB:

Sex: Male

Page 1 of 2

Anatomical Pathology

Lab #:

CLINICAL NOTES

Radical subtotal gastrectomy with separate hepatic artery subpyloric and gastric serosal nodule.

MACROSCOPIC DESCRIPTION

i. Specimen container labelled "radical subtotal gastrectomy": A subtotal gastrectomy specimen which measures up to 90mm from proximal to distal by up to 50mm by 30mm, with a small amount of attached greater omentums and lesser omentums. Lying 10mm from the distal resection margin is a geographic ulcer centred on the greater curve which measures up to 50mm from proximal to distal by up to 45mm. The floor of the ulcer has a covering of inflammatory slough. The serosa over this point appears indurated and focally nodular. The remaining gastric mucosa appears unremarkable. The ulcer lies at least 35mm from the proximal resection margin. Within the fat attached to the greater curve there is a large pale lymph node consistent with metastatic tumour. Blocks selected: (a-2 proximal resection margin, b-2 distal resection margin, c-1, d-1, e-1 tumour, f-x lesser curve nodes, g-x, h-x, g and h are from the greater curve)

ii. Specimen container labelled "left subpyloric gland": A pale lymph node measuring up to 20mm in maximum dimension, suggestive of metastatic carcinoma. Specimen bisected. Blocks selected: (a-2)

iii. Specimen container labelled "serosal lymph node": A fragment of pale tissue which does not exceed 3mm in maximum dimension. Blocks selected: (a-1)

iv. Specimen container labelled "hepatic artery gland": A multinodular mass of pale tissue suggestive of a replaced lymph node with a cut surface similar to that seen within specimen ii. The specimen measures up to 38mm in maximum dimension. Blocks selected: (a-1)

Registrar/Typist:

MICROSCOPIC DESCRIPTION

i. The tumour is a poorly differentiated gastric adenocarcinoma which is made up of sheets and cords of malignant cells extending through the muscularis propria and into the subserosal connective

A
N
8145/3
A
T
C16.0
O
M
I
C
A
L
P
A
T
H
O
L
O
G
Y

[page 2 of 3]
DOB

Sex: Male

Anatomical Pathology

Page 2 of 2

tissue. The tumour infiltrates under non-neoplastic mucosa in the adjacent stomach and permeates lymphatics in the region in and around the tumour.

Portions of upto 5 lymph nodes are present in the sections from the lesser curve nodes and these all show reactive change but no evidence of metastatic malignancy.

Sections of the tissue from the greater curve contain portions of upto 7 lymph nodes, one of which contains metastatic tumour with extra capsular extension.

Sections of the proximal resection margin are free of tumour. IN the sections from the distal resection margin there is tumour in lymphatics in the submucosa.

ii. Sections of the left subpyloric gland show almost complete effacement of the glandular architecture by metastatic deposits of tumour.

iii. Sections of the serosal "lymph node" contains some mildly inflamed connective tissue with a small area covered by hyperplastic mesothelial cells.

iv. Sections of the hepatic artery gland show a lymph node which is almost total replaced by metastatic deposits of the adenocarcinoma.

PATHOLOGIST'S OPINION

i. Poorly differentiated adenocarcinoma extending through the wall and into the subserosal connective tissue.

Proximal resection margin is free of tumour.

The distal resection margin tissue contains tumour emboli in the submucosal lymphatics.

Metastatic tumour is present in one of 7 lymph nodes from the greater curve region.

ii. Left subpyloric gland - Metastatic adenocarcinoma.

iii. Serosal lymph node - No evidence of tumour (the specimen comprises connective tissue only).

iv. Hepatic artery gland - Metastatic adenocarcinoma.

Registrar/Typist:

Pathologist:

*Per TSS dx discrepancy from
status TGA tumor to be
adenocarcinoma, diffuse type.*

Use of (circled) HPAA / DISQUALIFIED		

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	adenocarcinoma, NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma, diffuse type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subtype classification not specified in pathology report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my Institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 7bba27c5-6fd8-4d50-b45e-5a08e678181a (TCGA-RD-A8NB.7AE19967-2BE1-41D9-A628-B5F0392E1E53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).